Somatic mutation profile of tumor specimen TARGET-20-PANDER-09A (aliquot TARGET-20-PANDER-09A-02D) from TARGET case TARGET-20-PANDER, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.8 years (4,312 days).
Specimen TARGET-20-PANDER-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5d1c8b3-44c1-4147-b5ef-08004f73d3be.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PANDER-14A (Bone Marrow Normal), aliquot TARGET-20-PANDER-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c02e69a-5b50-4b16-8b3e-dbe2a742d5b3

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2464A>T p.N822Y | Missense Mutation (SNP) | VAF 8/171 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM087050, COSV55387376, COSV55389464; called by muse, mutect2
- C15orf39 | c.2102T>C p.V701A | Missense Mutation (SNP) | VAF 83/169 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV62297164; called by muse, mutect2, varscan2
- TET2 | c.5393C>A p.S1798* | Nonsense Mutation (SNP) | VAF 103/230 reads (45%) | catalogued as COSV54418269, COSV99036192; called by muse, mutect2, varscan2
- FLT3 | c.2511_2512insTCCG p.D839Efs*2 | Frame Shift Ins (INS) | VAF 85/237 reads (36%) | called by mutect2, varscan2
- FLT3 | c.2506_2510delinsTGTCC p.I836_M837delinsCP | Missense Mutation (ONP) | VAF 89/242 reads (37%) | called by mutect2*, pindel, varscan2*
